Somatic mutation profile of tumor specimen 0DB981 from CCDI case PBBKKT, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Vital status: Alive; Primary diagnosis: Glioma, malignant; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 13.0 years (4,750 days).
Specimen 0DB981: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ba41241b-8de9-4f87-9409-ed037ff5b6ba.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DB97O (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/384e09a1-07dd-4817-82a3-2231d7166f67

The open-access MAF lists 20 somatic variants for this specimen: 15 protein-altering or splice-affecting, 1 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 15, Intron 3, Silent 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 730/1827 reads (40%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.339); catalogued as rs121913237, COSV54736383, COSV54736555, COSV54736974; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- AMER3 | c.527C>T p.S176L | Missense Mutation (SNP) | VAF 423/969 reads (44%) | SIFT tolerated (1); PolyPhen benign (0.207); catalogued as rs139544644; called by muse, mutect2, varscan2
- CACNA1E | c.4037G>A p.R1346Q | Missense Mutation (SNP) | VAF 656/2362 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV104419924; called by muse, mutect2, varscan2
- DPY19L3 | c.1552A>G p.K518E | Missense Mutation (SNP) | VAF 227/554 reads (41%) | SIFT tolerated (1); PolyPhen benign (0.022); catalogued as rs1489581619, COSV60478961; called by muse, mutect2, varscan2
- KBTBD13 | c.809C>T p.T270M | Missense Mutation (SNP) | VAF 188/975 reads (19%) | SIFT tolerated (0.34); PolyPhen benign (0.014); catalogued as rs750447903, COSV101416693; called by muse, mutect2
- UNC79 | c.5873C>T p.T1958M (on ENST00000393151 / NM_001346218.2; = p.T1781M on NM_020818.5) | Missense Mutation (SNP) | VAF 708/1094 reads (65%) | SIFT tolerated, low confidence (0.51); PolyPhen benign (0); catalogued as COSV56400167; called by muse, mutect2, varscan2
- VCPIP1 | c.2123A>G p.N708S | Missense Mutation (SNP) | VAF 497/1167 reads (43%) | SIFT tolerated (0.34); PolyPhen benign (0.027); catalogued as rs775513826; called by muse, mutect2, varscan2
- ZFYVE26 | c.4433C>T p.A1478V | Missense Mutation (SNP) | VAF 526/812 reads (65%) | SIFT tolerated (0.17); PolyPhen benign (0.017); catalogued as COSV61331896; called by muse, mutect2, varscan2
- ACOD1 | c.188A>G p.N63S | Missense Mutation (SNP) | VAF 63/1795 reads (4%) | SIFT tolerated (0.7); PolyPhen benign (0.005); called by muse, mutect2
- AHI1 | c.1214C>A p.T405N | Missense Mutation (SNP) | VAF 483/1236 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.661); called by muse, mutect2, varscan2
- ELF4 | c.103G>A p.V35M | Missense Mutation (SNP) | VAF 60/615 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- FKBP5 | c.1122T>G p.F374L | Missense Mutation (SNP) | VAF 557/1402 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- HLTF | c.2692C>G p.Q898E | Missense Mutation (SNP) | VAF 63/2420 reads (3%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.947); called by muse, mutect2
- SRCIN1 | c.584G>A p.R195H (on ENST00000621492; = p.R161H on NM_025248.3) | Missense Mutation (SNP) | VAF 165/715 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- TMEM79 | c.710T>G p.I237S | Missense Mutation (SNP) | VAF 550/2022 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.079); called by muse, mutect2, varscan2
- FBLN2 | c.3327G>A p.A1109= | Silent (SNP) | VAF 385/767 reads (50%) | catalogued as rs746614248, COSV55486933; called by muse, mutect2, varscan2
- CALCOCO2 | c.825+76T>A | Intron (SNP) | VAF 20/350 reads (6%) | called by muse, mutect2
- EPB41L1 | c.-6G>C | 5'UTR (SNP) | VAF 281/678 reads (41%) | called by muse, mutect2, varscan2
- LAMA4 | c.2173+75G>C | Intron (SNP) | VAF 103/201 reads (51%) | called by muse, mutect2, varscan2
- PPP6R1 | c.731+28G>T | Intron (SNP) | VAF 182/399 reads (46%) | catalogued as rs544056480; called by muse, mutect2, varscan2
